Somatic mutation profile of tumor specimen 9f905736-f662-41d6-b3ac-16758d (aliquot CPT0053040010) from CPTAC case 11LU013, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 59.2 years (21,627 days).
Specimen 9f905736-f662-41d6-b3ac-16758d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29612340-6316-4225-a5a3-9c6dc9a66db4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c7788b82-8190-4784-ab76-0d1185 (Blood Derived Normal), aliquot CPT0040210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac9aba0d-dc3c-4d84-9fda-8405a5908ad0

The open-access MAF lists 86 somatic variants for this specimen: 58 protein-altering or splice-affecting, 13 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 13, Intron 6, 3'Flank 3, Nonsense Mutation 3, RNA 3, 5'UTR 2, Splice Site 1, In Frame Ins 1, Frame Shift Del 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 76/266 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO7 | c.899C>T p.T300M (on ENST00000274979; = p.T246M on NM_001370694.2) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs374614039; called by muse, mutect2, varscan2
- APLNR | c.989G>T p.R330M | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs755331397; called by muse, mutect2, varscan2
- CDC14C | c.1088C>T p.A363V (on ENST00000428251; = p.A256V on NM_152627.3) | Missense Mutation (SNP) | VAF 44/501 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs775488250; called by muse, mutect2
- CHD8 | c.5323C>T p.R1775W (on ENST00000646647 / NM_001170629.2; = p.R1496W on NM_020920.4) | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs536360321; called by muse, mutect2, varscan2
- COL12A1 | c.6459G>C p.V2153= | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100486491; called by muse, mutect2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 175/700 reads (25%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- FBRSL1 | c.2845C>T p.R949W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1336008911; called by muse, mutect2, varscan2
- FIBCD1 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs572135699; called by muse, mutect2
- GPR107 | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1455878923; called by muse, mutect2, varscan2
- GRK4 | c.1271T>A p.L424* (on ENST00000398052 / NM_182982.3; = p.L392* on NM_005307.3) | Nonsense Mutation (SNP) | VAF 102/420 reads (24%) | catalogued as rs767948389; called by muse, mutect2, varscan2
- GTPBP4 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs201885506; called by muse, mutect2, varscan2
- HECW1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs761812388, COSV104431278; called by muse, mutect2, varscan2
- IGF2BP3 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 11/266 reads (4%) | catalogued as COSV51687998; called by muse, mutect2
- KLHL35 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs751493702; called by muse, mutect2, varscan2
- KLK8 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs371793414; called by muse, mutect2
- LMX1A | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs909983869, COSV54218563, COSV99672908; called by muse, mutect2, varscan2
- MARCHF4 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs367784136, COSV99814011; called by muse, mutect2, varscan2
- MMEL1 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1287020426; called by muse, mutect2, varscan2
- MUC16 | c.13597C>A p.P4533T | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.556); catalogued as COSV67454328; called by muse, mutect2, varscan2
- NBPF15 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 29/987 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs1351126048; called by muse, mutect2
- NELFA | c.986C>T p.A329V (on ENST00000542778; = p.A318V on NM_005663.5) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs868120810, COSV100373717; called by muse, mutect2, varscan2
- NIM1K | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58141707; called by muse, mutect2
- OR10H5 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as rs758339662; called by muse, mutect2, varscan2
- PCDH8 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs752568356; called by muse, mutect2, varscan2
- PCDHGA2 | c.1953G>T p.Q651H | Missense Mutation (SNP) | VAF 71/641 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54004544; called by muse, mutect2, varscan2
- PROP1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 93/277 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749868829; called by muse, mutect2, varscan2
- RYR3 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.29); catalogued as rs371947863; called by muse, mutect2, varscan2
- SALL1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs997918353; called by muse, mutect2, varscan2
- TAS2R7 | c.791A>G p.E264G | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as COSV53688278, COSV53690811; called by muse, mutect2
- TPO | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs934688438; called by muse, mutect2, varscan2
- TRAV2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 103/395 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1366474230; called by muse, mutect2, varscan2
- ANO10 | c.235A>T p.M79L | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP3 | c.992T>A p.V331E | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CALCOCO1 | c.1403G>A p.S468N | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CELSR1 | c.8222A>G p.N2741S | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CPA1 | c.132C>A p.D44E | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPXCR1 | c.792T>A p.N264K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ENC1 | c.1628_1634del p.V543Dfs*18 | Frame Shift Del (DEL) | VAF 38/300 reads (13%) | called by mutect2, pindel
- ERCC4 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- FAM184A | c.3361T>G p.S1121A | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- FGB | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 29/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGA4 | c.651_656dup p.D218_Q219dup | In Frame Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, varscan2
- HEPACAM2 | c.566T>C p.V189A (on ENST00000394468 / NM_001039372.4; = p.V177A on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/493 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2
- LRRFIP2 | c.1024_1035+14del p.X342_splice | Splice Site (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel
- MYH9 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 67/487 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR52A1 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OXR1 | c.1424C>T p.A475V (on ENST00000442977 / NM_001198532.1; = p.A474V on NM_018002.3) | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- PCDHB15 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 243/796 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- PLA2G7 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RAB30 | c.199G>C p.G67R | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM15B | c.1739C>A p.A580E | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS1 | c.2477G>C p.R826P | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROBO4 | c.1036G>C p.V346L | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- TRIML2 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- UBAP2L | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- WDR7 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZBTB45 | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ADAT3 | c.906G>A p.V302= | Silent (SNP) | VAF 64/625 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP11A | c.226T>C p.L76= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- COL4A5 | c.4626A>G p.P1542= | Silent (SNP) | VAF 84/274 reads (31%) | called by muse, mutect2, varscan2
- GLB1 | c.682C>T p.L228= | Silent (SNP) | VAF 44/355 reads (12%) | catalogued as rs1473132094; called by muse, mutect2, varscan2
- LRP12 | c.507T>C p.D169= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV99407357; called by mutect2, varscan2
- NR2F2 | c.582G>A p.S194= | Silent (SNP) | VAF 99/300 reads (33%) | catalogued as rs1398289040; called by muse, mutect2, varscan2
- PDE4D | c.255G>A p.P85= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- PDGFRB | c.2136C>T p.S712= | Silent (SNP) | VAF 27/292 reads (9%) | catalogued as rs1312846795, COSV55811975; called by muse, mutect2, varscan2
- PGRMC1 | c.42C>T p.S14= | Silent (SNP) | VAF 88/295 reads (30%) | called by muse, mutect2, varscan2
- PYGM | c.1251C>T p.A417= | Silent (SNP) | VAF 116/634 reads (18%) | catalogued as rs1328262607; called by muse, mutect2, varscan2
- RYR2 | c.7569C>A p.A2523= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as rs748943528, COSV63715566; called by muse, mutect2, varscan2
- SLC30A10 | c.276C>G p.L92= | Silent (SNP) | VAF 46/640 reads (7%) | called by muse, mutect2
- TNR | c.2547C>T p.G849= | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2
- CDH9 | c.999+155G>T | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- CTTN | c.*553A>G | 3'UTR (SNP) | VAF 72/603 reads (12%) | catalogued as rs1304157449; called by muse, mutect2, varscan2
- DST | c.4296+3990G>A | Intron (SNP) | VAF 44/171 reads (26%) | called by muse, mutect2, varscan2
- EFNA5 | c.418+55T>G | Intron (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- FCER1G | c.-15G>T | 5'UTR (SNP) | VAF 19/298 reads (6%) | catalogued as COSV99248436; called by muse, mutect2
- GLB1L2 | c.-36G>A | 5'UTR (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- GSS | c.351+15C>T | Intron (SNP) | VAF 107/625 reads (17%) | called by muse, mutect2, varscan2
- HGSNAT | c.1465-448T>C | Intron (SNP) | VAF 22/355 reads (6%) | called by muse, mutect2
- MYL3 | chr3:46833553 G>A | 3'Flank (SNP) | VAF 10/188 reads (5%) | catalogued as rs1470208126; called by muse, mutect2
- NPIPB1P | n.397C>A | RNA (SNP) | VAF 85/750 reads (11%) | called by muse, mutect2, varscan2
- PIPSL | n.989C>T | RNA (SNP) | VAF 57/409 reads (14%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.566G>A | RNA (SNP) | VAF 33/295 reads (11%) | catalogued as rs1219089320; called by muse, mutect2, varscan2
- STAU2 | chr8:73420206 G>A | 3'Flank (SNP) | VAF 21/318 reads (7%) | catalogued as rs1186072463; called by muse, mutect2
- SYNCRIP | chr6:85612885 T>C | 3'Flank (SNP) | VAF 51/193 reads (26%) | catalogued as rs567244634; called by muse, mutect2, varscan2
- TTC23 | c.1144-137A>C | Intron (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
